Somatic mutation profile of tumor specimen C3N-01505-01 (aliquot CPT0089150009) from CPTAC case C3N-01505, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.3 years (27,131 days).
Specimen C3N-01505-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8331e5e-a63e-4727-94c0-1468602a86d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01505-31 (Blood Derived Normal), aliquot CPT0091300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4d6e03b-10ec-4db8-bfbf-8d1cecfd5a86

The open-access MAF lists 88 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 20, Nonsense Mutation 4, Frame Shift Del 4, Intron 3, RNA 2, Splice Region 2, 5'UTR 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.492+1del | Frame Shift Del (DEL) | VAF 115/328 reads (35%) | catalogued as rs1564830522; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACACB | c.4534G>A p.A1512T | Missense Mutation (SNP) | VAF 151/588 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs779472077; called by muse, mutect2, varscan2
- ALMS1 | c.11413C>T p.R3805* | Nonsense Mutation (SNP) | VAF 42/186 reads (23%) | catalogued as rs376091780, CM050173, COSV52519626; called by muse, mutect2, varscan2
- APOB | c.7600C>T p.R2534* | Nonsense Mutation (SNP) | VAF 107/339 reads (32%) | catalogued as rs145143533, CM051005; ClinVar: benign; called by muse, mutect2, varscan2
- ARHGAP18 | c.1545_1548del p.I516Sfs*14 | Frame Shift Del (DEL) | VAF 58/233 reads (25%) | catalogued as rs748022405; called by mutect2, pindel, varscan2
- BCAM | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs556440715; called by muse, mutect2, varscan2
- BRD9 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs1400151697, COSV60247841; called by muse, mutect2, varscan2
- C1orf127 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.151); catalogued as rs1288556051; called by muse, mutect2, varscan2
- CDH7 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.357); catalogued as rs767686297, COSV59883221; called by muse, mutect2, varscan2
- COG7 | c.1019A>G p.N340S | Missense Mutation (SNP) | VAF 136/516 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.084); catalogued as rs994816379, COSV56151111; called by muse, mutect2, varscan2
- DEFB110 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.882); catalogued as rs1484799665, COSV67017940; called by muse, mutect2, varscan2
- DNAH6 | c.4612G>A p.A1538T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375217652, COSV52883424; called by muse, mutect2, varscan2
- GABRR1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs571678202, COSV65618820; called by muse, mutect2, varscan2
- GRIN2B | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 113/474 reads (24%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.955); catalogued as rs748075089, COSV101663194, COSV74205288; called by muse, mutect2, varscan2
- GRM1 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 122/388 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs773266243, COSV51367039; called by muse, varscan2
- HMCN1 | c.1121C>A p.T374N | Missense Mutation (SNP) | VAF 27/391 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV54914446; called by muse, mutect2
- IFIH1 | c.1405A>G p.N469D | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1253953605; called by muse, mutect2, varscan2
- IPO5 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1372225798, COSV55158030; called by muse, mutect2, varscan2
- ITGAE | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs369079712; called by muse, mutect2, varscan2
- LGI3 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757547343, COSV60443691; called by muse, mutect2, varscan2
- MAP3K9 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 104/391 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs747019799; called by muse, mutect2, varscan2
- OR4C46 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 129/436 reads (30%) | catalogued as rs775929413, COSV100060502; called by muse, mutect2, varscan2
- OR56A3 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs957219841, COSV61568454; called by muse, mutect2, varscan2
- OR6B3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as rs1303272399; called by muse, mutect2, varscan2
- OR6P1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 137/544 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs551351648, COSV58109868, COSV58110159; called by muse, mutect2, varscan2
- PLEKHG4B | c.1919C>T p.T640M (on ENST00000283426; = p.T996M on NM_052909.5) | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs542561152; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.474); catalogued as rs1318722096, COSV100982313, COSV65048929; called by muse, mutect2, varscan2
- PXDN | c.1799T>C p.I600T | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs766897132; called by muse, mutect2, varscan2
- RUNX1 | c.836G>A p.R279H (on ENST00000344691 / NM_001001890.3; = p.R306H on NM_001754.5) | Missense Mutation (SNP) | VAF 121/464 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs139336358, COSV100277668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD11 | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as rs910296298; called by muse, mutect2, varscan2
- SESTD1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 117/452 reads (26%) | catalogued as COSV58931426; called by muse, mutect2, varscan2
- TMPRSS11B | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs575638339; called by muse, mutect2, varscan2
- XDH | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764753696, COSV65150112; called by muse, mutect2, varscan2
- XKR7 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.769); catalogued as rs781133344, COSV73813021, COSV73813122; called by muse, mutect2, varscan2
- ZNF735 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs773098060, COSV70034667; called by muse, mutect2, varscan2
- ZNF804B | c.1268A>C p.N423T | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV60833412; called by muse, mutect2, varscan2
- APOB | c.13002C>A p.N4334K | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- ATP8A2 | c.1640C>A p.P547Q | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC58 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 103/396 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CEP250 | c.2969del p.D990Afs*26 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7300A>T p.I2434F (on ENST00000297405 / NM_001363185.1; = p.I2330F on NM_052900.3) | Missense Mutation (SNP) | VAF 139/460 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CYP2B6 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 224/853 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- EHBP1L1 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EIF4G2 | c.759C>G p.C253W | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FHL1 | c.-169G>A | Splice Region (SNP) | VAF 122/215 reads (57%) | called by muse, varscan2
- FRRS1L | c.566del p.P189Lfs*22 | Frame Shift Del (DEL) | VAF 86/435 reads (20%) | called by mutect2, pindel, varscan2
- IGKV1-8 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 112/407 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- KCNQ2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1614 | c.3320G>A p.S1107N | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC12 | c.10295C>G p.S3432C (on ENST00000379442; = p.S3289C on NM_001164462.1) | Missense Mutation (SNP) | VAF 112/3998 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2
- NAALAD2 | c.523T>A p.F175I | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX2-6 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- PIAS4 | c.909C>G p.V303= | Splice Region (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- PRODH2 | c.902C>A p.A301E (on ENST00000301175; = p.A225E on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, varscan2
- RBBP6 | c.2681T>C p.I894T | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF32 | c.15+2T>C p.X5_splice | Splice Site (SNP) | VAF 66/281 reads (23%) | called by muse, mutect2, varscan2
- SLC41A1 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 177/712 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D9 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- TMEFF1 | c.404dup p.T136Nfs*11 | Frame Shift Ins (INS) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- TPP2 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- USP18 | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ADGRF5 | c.1458A>G p.Q486= | Silent (SNP) | VAF 105/428 reads (25%) | called by muse, mutect2, varscan2
- BTNL8 | c.1053A>G p.K351= | Silent (SNP) | VAF 129/275 reads (47%) | called by muse, mutect2, varscan2
- CFAP58 | c.1200C>A p.T400= | Silent (SNP) | VAF 60/148 reads (41%) | called by muse, mutect2, varscan2
- COL5A1 | c.3483C>T p.I1161= | Silent (SNP) | VAF 66/241 reads (27%) | catalogued as rs576483507; called by muse, mutect2, varscan2
- DSC2 | c.1614G>A p.E538= | Silent (SNP) | VAF 120/464 reads (26%) | catalogued as COSV51865003, COSV51865325; called by muse, mutect2, varscan2
- IGFN1 | c.3216G>A p.P1072= (on ENST00000295591 / NM_001367841.1; = p.P3529= on NM_001164586.2) | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs761660706, COSV99811392; called by muse, mutect2, varscan2
- MS4A8 | c.258C>T p.L86= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- MYBPC3 | c.1671C>T p.G557= | Silent (SNP) | VAF 68/223 reads (30%) | catalogued as rs751052593, COSV57031940; called by muse, mutect2, varscan2
- NSD3 | c.2724T>G p.P908= | Silent (SNP) | VAF 57/226 reads (25%) | called by muse, mutect2, varscan2
- OTOGL | c.4368A>T p.P1456= (on ENST00000547103; = p.P1447= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 63/202 reads (31%) | called by muse, mutect2, varscan2
- PBRM1 | c.690C>T p.L230= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- PCDHA3 | c.1557G>A p.A519= | Silent (SNP) | VAF 247/929 reads (27%) | catalogued as rs571219787; called by muse, mutect2, varscan2
- PDE4A | c.573C>A p.V191= | Silent (SNP) | VAF 83/356 reads (23%) | called by muse, mutect2, varscan2
- PDGFRB | c.696C>T p.T232= | Silent (SNP) | VAF 99/375 reads (26%) | called by muse, mutect2, varscan2
- PLCB3 | c.66G>T p.L22= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- SAMHD1 | c.483A>T p.S161= | Silent (SNP) | VAF 48/574 reads (8%) | called by muse, mutect2
- SLC19A1 | c.1029G>A p.T343= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs140092730, COSV100229103; called by muse, mutect2
- SYNDIG1L | c.705C>T p.N235= | Silent (SNP) | VAF 95/390 reads (24%) | catalogued as rs764855912, COSV100526538; called by muse, mutect2, varscan2
- TMEM132D | c.24G>A p.T8= | Silent (SNP) | VAF 49/244 reads (20%) | called by muse, mutect2, varscan2
- TRBV27 | c.165A>G p.R55= | Silent (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- ABAT | c.317-514A>G | Intron (SNP) | VAF 28/97 reads (29%) | catalogued as rs773265550, COSV51625674; called by muse, mutect2, varscan2
- CHRNA4 | c.274-16G>A | Intron (SNP) | VAF 38/132 reads (29%) | catalogued as rs201948072; called by muse, mutect2, varscan2
- CNOT10 | c.23-8125C>T | Intron (SNP) | VAF 138/503 reads (27%) | called by muse, mutect2, varscan2
- DPY19L2P1 | n.451A>G | RNA (SNP) | VAF 70/366 reads (19%) | called by muse, mutect2, varscan2
- OR4C4P | n.380G>A | RNA (SNP) | VAF 103/377 reads (27%) | catalogued as rs574387385; called by muse, mutect2, varscan2
- SNX21 | c.-8G>A | 5'UTR (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- TPRX1 | c.-154C>A | 5'UTR (SNP) | VAF 20/60 reads (33%) | called by mutect2, varscan2
